Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6917, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6917-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 3

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Total resection of organ – rectum**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Cancer of the rectum**

Examination performed on:

Macroscopic description:

30 cm length of large intestine with fat tissue of 1 cm in thickness.

Ulceration thickened at ends sized 6 x 4 cm.

The lesion surrounds 100% of the intestine circumference, narrowing its lumen, placed 14 cm from the proximal cut end, 6 cm from the distal cut end. Macroscopically, the lesion invades through the mesorectum tissue. Minimum side margin 0.1 cm

Microscopic description:

Adenocarcinoma tubulare solidum partim mucinosum (G3).

Infiltratio carcinomatosa telae adiposae mesorecti.

Intestine ends free of neoplastic lesions.

Metastases carcinomatosae in lymphonodis (No III/XIV).

Histopathological diagnosis:

Adenocarcinoma tubulare et partim mucinosum recti. Tubular and in part mucinous adenocarcinoma of the rectum.

Metastases carcinomatosae in lymphonodis regionalis. Cancer metastases in regional lymph nodes. (No III/XIV) (G3, Dukes C, Astler-Coller C2, pT3, pN1, R0).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 77579e03-145b-4c72-847c-516fcecb6ddb (TCGA-EI-6917.CA57373C-5E06-4BB0-96E4-812E36C79C17.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).